CCG case CUPP-B5XL — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0d382d8b-5632-42a2-a9a9-8ae871f42958

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Japan; Year of birth: 1945; Vital status: Dead; Days to death: 31 days; Year of death: 2015; Cause of death: Cancer Related.

Diagnoses (3)
1. Carcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8010/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 70.3 years (25,680 days); Year of diagnosis: 2015; Method of diagnosis: Biopsy; AJCC staging edition: 8th; AJCC clinical T: TX; AJCC clinical N: N2; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: TX; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 1; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R2; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS, postoperative.
2. Prior malignancy of the stomach (histology not recorded by GDC).
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Progression (histology not recorded by GDC). Age at diagnosis: 70.4 years (25,711 days); Year of diagnosis: 2015; Days to diagnosis: 31 days.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 20; ECOG performance status: 4.
- Day 31 (progression): Disease response: With Tumor; Progression or recurrence: Yes; Days to progression: 31 days.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 49 kg; Height: 168 cm; BMI: 17.4.
- Timepoint category: Prior to Diagnosis; Comorbidities: COPD.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 45; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 2010.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Cancer; Relationship sex at birth: male.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B5XL-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B5XL-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
